TCGA case TCGA-WZ-A8D5 — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8ed15b85-5bb3-4317-a93d-67ee376a8244

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 38 years; Year of birth: 1974; Vital status: Alive.

Diagnoses (1)
1. Seminoma, NOS: ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 38.3 years (13,974 days); Year of diagnosis: 2012; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 774 days (2.1 years); Ajcc serum tumor markers: SX.
   Pathology details: Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 46 days; Days to treatment end: 71 days; Treatment dose: 2,500 cGy; Treatment outcome: Complete Response; Number of fractions: 20; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 25 days; Disease response: Tumor Free.
- Days to follow up: 774 days (2.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -8: Lactate Dehydrogenase 678; Alpha Fetoprotein 1.5; Human Chorionic Gonadotropin 1.2.
- Day 116: Alpha Fetoprotein 1.9; Human Chorionic Gonadotropin 1.2.

Family history
- Relative with cancer history: no.
- Relative with cancer history: yes; Relationship type: Natural Father; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WZ-A8D5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 30 mg.
  Slide TCGA-WZ-A8D5-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample TCGA-WZ-A8D5-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WZ-A8D5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; History hypospadias: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Testes; Lymphovascular invasion: Yes.
- Primary pathology, Histology list, Histology: Histologic diagnosis: Seminoma, NOS; Histologic diagnosis percent: 100.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 678; Pre orchi hcg: 1.2; Pre orchi afp: 1.5.
- Primary pathology, Post orchi serum marker info: Post orchi hcg: 1.2; Post orchi afp: 1.9.
- Follow-up form: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: No Measureable Tumor or Tumor Markers; New tumor event diagnosis indicator: No.
- Follow-up form, Molecular test result list: Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 774 days; disease-specific survival: no event (censored), 774 days; disease-free interval: no event (censored), 774 days; progression-free interval: no event (censored), 774 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WZ-A8D5-01A-11D-A434-01): tumor purity 0.26, ploidy 4.42, whole-genome doublings 2.
